Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEW, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAEW-01A (Primary Tumor).

Department of Pathology

ICD O-3
Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
JW 3/3/14

Direct dial
Mobile:
Internal postal address
E-mail
Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 6 cm; lymphatic invasion present; invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file c65a785d-79ff-411b-81cc-8d2df29b7af7 (TCGA-2G-AAEW.02452377-4D36-4145-8492-B12046B855FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).